Somatic mutation profile of tumor specimen TCGA-KL-8323-01A (aliquot TCGA-KL-8323-01A-21D-2310-10) from TCGA case TCGA-KL-8323, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 57.1 years (20,849 days).
Specimen TCGA-KL-8323-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b7bba8e-75fe-4fc3-a6ca-2eaf75847d80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8323-11A (Solid Tissue Normal), aliquot TCGA-KL-8323-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43315bcd-2433-40dc-b937-804f12fe9d65

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Splice Region 1, Intron 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADH4 | c.18+5G>T | Splice Region (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99644345; called by muse, mutect2, varscan2
- CACNA1A | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs1555774867; ClinVar: uncertain significance; called by muse, mutect2
- CFAP47 | c.5092C>T p.R1698W | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs749241599, COSV57971117; called by muse, mutect2, varscan2
- GPR27 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1338031636; called by muse, mutect2, varscan2
- KRT20 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1439265018, COSV51424526; called by muse, mutect2, varscan2
- PHRF1 | c.1203G>T p.R401S | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV52755269; called by muse, mutect2, varscan2
- PTEN | c.584T>C p.F195S | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64303833; called by muse, mutect2, varscan2
- PTPRN2 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as rs370624864; called by muse, mutect2, varscan2
- THADA | c.5174A>G p.D1725G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV100369306; called by muse, mutect2, varscan2
- ZBBX | c.2267A>G p.E756G | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100284745; called by muse, varscan2
- MED17 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NCKAP5L | c.3955C>G p.L1319V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NMRK1 | c.512C>A p.T171K | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- NOXA1 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.55); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- POU5F2 | c.877C>G p.H293D | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFSF13 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- UBR4 | c.6544C>A p.Q2182K | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- UBR4 | c.6543G>T p.Q2181H | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- USP9X | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ASIC3 | c.45G>A p.S15= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs369122567; called by mutect2, varscan2
- CUBN | c.6624C>T p.I2208= | Silent (SNP) | VAF 13/93 reads (14%) | called by muse, mutect2, varscan2
- MAPK7 | c.852C>T p.A284= | Silent (SNP) | VAF 31/35 reads (89%) | catalogued as rs145605078; called by muse, mutect2, varscan2
- NTRK3 | c.285C>T p.N95= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as rs536176882; called by muse, mutect2, varscan2
- SFI1 | c.1929C>T p.D643= (on ENST00000400288 / NM_001007467.3; = p.D612= on NM_014775.4) | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV101192223; called by muse, mutect2, varscan2
- TLNRD1 | c.1041G>A p.R347= | Silent (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- DNM1 | c.1672-1626C>G | Intron (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100360247; called by muse, mutect2, varscan2
- MAGEA5 | chrX:152115557 G>A | 5'Flank (SNP) | VAF 36/103 reads (35%) | catalogued as rs186697412; called by muse, mutect2, varscan2
- ZBTB33 | c.*2838G>A | 3'UTR (SNP) | VAF 12/212 reads (6%) | catalogued as COSV100434295; called by muse, mutect2
